Gene-level copy-number profile of tumor specimen TCGA-ER-A2NB-01A from TCGA case TCGA-ER-A2NB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.7 years (21,062 days).
Specimen TCGA-ER-A2NB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.9870fb23-74f6-4ac4-9a28-c771dc2f477c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A2NB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/55331ab6-e320-4429-9c53-69f81582bdb6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,719; copy number 3: 13,536; copy number 4: 24,194; copy number 5: 7,569; copy number 6: 5,003; copy number 7: 483; copy number 8: 2,436; copy number 9: 264; copy number 10: 40; copy number 11: 576.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A2NB-01A-12D-A194-01): tumor purity 0.29, ploidy 4.37, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 880 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:213,492,288–227,706,699, 237 genes, copy number 9 (broad region; genes not listed).
- chr6:63,193,072–65,707,226, 24 genes, copy number 9: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr6:66,093,431–66,728,904, 3 genes, copy number 9: NUFIP1P1, AL450336.1, RNU7-66P.
- chr7:70,972–32,791,946, 576 genes, copy number 11 (broad region; genes not listed).
- chr22:40,346,500–41,399,326, 40 genes, copy number 10 (within-gene range 6–10): ADSL, AL022238.3, SGSM3, SGSM3-AS1, MRTFA, AL022238.2, AL022238.1, MRTFA-AS1, COX6B1P3, RPL4P6, GAPDHP37, MCHR1, SLC25A17, Z98048.1, JTBP1, MIR4766, ST13, XPNPEP3, DNAJB7, Metazoa_SRP, RNU6-379P, RBX1, Y_RNA, AL080243.2, Y_RNA, AL080243.1, MIR1281, EP300, RNU6-375P, AL035658.1, EP300-AS1, LRRC37A14P, L3MBTL2, L3MBTL2-AS1, CHADL, RANGAP1, MIR6889, ZC3H7B, TEF, RNU6-495P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
